Surgical pathology report (de-identified scan), TCGA case TCGA-B0-5120, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-5120-01A (Primary Tumor).

AL DIAGNOSIS

PART 1: ADIPOSE, PERI-TUMOR, EXCISION -
UNREMARKABLE MATURE, LOBULATED ADIPOSE TISSUE.

PART 2: KIDNEY, LEFT, PARTIAL NEPHRECTOMY -
A. RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR CELL) TYPE.
B. FUHRMAN NUCLEAR GRADE IS 2 OF 4.
C. THE GREATEST DIAMETER OF THE NEOPLASM IS 3.8 CM.
D. THE NEOPLASM IS CONFINED WITHIN THE RENAL CAPSULE.
E. NO EVIDENCE OF ANGIOLYMPHATIC INVASION IS IDENTIFIED.
F. ALL SURGICAL MARGINS ARE FREE OF THE NEOPLASM.
G. THE NON-NEOPLASTIC KIDNEY SHOWS NO SIGNIFICANT PATHOLOGIC ABNORMALITY.
H. TNM PATHOLOGIC STAGE: pT1a NX MX (SEE SYNOPSIS).

PART 3: KIDNEY, "DEEP MARGIN #1", BIOPSY -
UNREMARKABLE RENAL PARENCHYMA AND FIBROCONNECTIVE TISSUE, NEGATIVE FOR TUMOR.

PART 4: KIDNEY, "DEEP MARGIN #2", BIOPSY -
UNREMARKABLE RENAL PARENCHYMA, NEGATIVE FOR TUMOR.

PART 5: KIDNEY, "DEEP MARGIN #3", BIOPSY -
UNREMARKABLE MATURE, LOBULATED ADIPOSE TISSUE, NEGATIVE FOR TUMOR.

Source: NCI Genomic Data Commons file e7f20039-4c79-4f1f-add3-025675dfab29 (TCGA-B0-5120.8A0DBCC3-83F1-41B1-BF99-63B4D13A2B02.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).